Somatic mutation profile of tumor specimen TCGA-CM-6166-01A (aliquot TCGA-CM-6166-01A-11D-1650-10) from TCGA case TCGA-CM-6166, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 48.8 years (17,807 days).
Specimen TCGA-CM-6166-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94725fef-6a9b-46cb-904b-ff7187f43d3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6166-10A (Blood Derived Normal), aliquot TCGA-CM-6166-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f4d3f6d-f993-4db6-97ce-ff7b12de233a

The open-access MAF lists 87 somatic variants for this specimen: 67 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 18, Splice Site 3, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 137/166 reads (83%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- AC104452.1 | c.1028T>A p.L343Q | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99864646; called by muse, mutect2, varscan2
- ADAMTS1 | c.2642G>T p.C881F | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53172767; called by muse, mutect2
- ADGRA3 | c.1658C>T p.T553M | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs186077400; called by muse, mutect2, varscan2
- ADGRB3 | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748082885, COSV65414311; called by muse, mutect2, varscan2
- AKT1 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs774836044, COSV62575451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP002512.3 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 63/98 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs199694619, COSV54405850; called by muse, mutect2, varscan2
- APC | c.3980C>T p.S1327L | Missense Mutation (SNP) | VAF 78/205 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs1554085429, COSV57323640, COSV57335489, COSV57371230; ClinVar: uncertain significance; called by muse, varscan2
- BRD7 | c.591+1G>A p.X197_splice | Splice Site (SNP) | VAF 207/421 reads (49%) | catalogued as COSV67159801, COSV67159994; called by muse, mutect2, varscan2
- BTAF1 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765162182, COSV56438162, COSV99795959; called by muse, mutect2, varscan2
- C6orf118 | c.1344G>T p.K448N | Missense Mutation (SNP) | VAF 48/532 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.413); catalogued as COSV57817972; called by muse, mutect2
- CADPS | c.3391C>T p.P1131S | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV51897049; called by muse, mutect2, varscan2
- CALR3 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs1387247680, COSV99522246; called by muse, mutect2, varscan2
- CDR2L | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.724); catalogued as rs368260807; called by muse, mutect2, varscan2
- CLK1 | c.665+1G>C p.X222_splice | Splice Site (SNP) | VAF 117/361 reads (32%) | catalogued as COSV58435340; called by muse, mutect2, varscan2
- CLSPN | c.3814C>T p.H1272Y | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV52055967; called by muse, mutect2, varscan2
- CNTNAP4 | c.3196C>A p.L1066I | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.597); catalogued as rs769260762, COSV56696133; called by muse, mutect2, varscan2
- COPB2 | c.357T>G p.D119E | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60813623; called by muse, mutect2, varscan2
- CWC27 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 100/248 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV66888218; called by muse, mutect2, varscan2
- CYP27C1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761337472, COSV58867602; called by muse, mutect2, varscan2
- CYP2A6 | c.901G>T p.G301W | Missense Mutation (SNP) | VAF 177/321 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV56536681; called by muse, mutect2, varscan2
- DNAH5 | c.3056C>A p.P1019H | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99451200; called by muse, mutect2, varscan2
- DOCK1 | c.4141G>A p.A1381T | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs778556643, COSV54729048; called by muse, mutect2, varscan2
- EPHX3 | c.256C>A p.R86S | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV54585966, COSV54592576; called by muse, mutect2, varscan2
- EPN2 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as rs772339966, COSV59063109; called by muse, mutect2, varscan2
- ERGIC3 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as rs139314230; called by muse, mutect2
- FBN1 | c.2288G>T p.C763F | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57327366; called by muse, mutect2, varscan2
- FLRT2 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV58148222; called by muse, mutect2, varscan2
- FOXC2 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV57445172; called by muse, mutect2, varscan2
- KDM1A | c.1774C>T p.Q592* | Nonsense Mutation (SNP) | VAF 27/71 reads (38%) | catalogued as COSV63089663; called by muse, mutect2, varscan2
- LOXL3 | c.824dup p.A277Cfs*57 | Frame Shift Ins (INS) | VAF 28/114 reads (25%) | catalogued as rs746133895; called by mutect2, varscan2
- LRP1 | c.11105G>A p.R3702H | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs141307381; called by muse, mutect2, varscan2
- MAP1A | c.848T>A p.L283H | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55811672; called by muse, mutect2, varscan2
- MEGF6 | c.3049C>A p.Q1017K | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.23); catalogued as COSV53894643; called by muse, mutect2, varscan2
- MMP17 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 100/122 reads (82%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.839); catalogued as rs374439053; called by muse, mutect2, varscan2
- MSRA | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1448031427, COSV57809344; called by muse, mutect2, varscan2
- NEXMIF | c.2822G>T p.G941V | Missense Mutation (SNP) | VAF 133/615 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.054); catalogued as COSV50077833; called by muse, mutect2, varscan2
- OR2T12 | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 244/593 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58779073; called by muse, varscan2
- OR2T12 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 252/705 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as rs145703258; called by muse, varscan2
- OR2Y1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1452453923, COSV57136131; called by muse, mutect2, varscan2
- PCDHA3 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV63545015; called by muse, mutect2, varscan2
- PEG3 | c.3088C>T p.R1030W | Missense Mutation (SNP) | VAF 107/402 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs368105379; called by muse, mutect2, varscan2
- PIK3CG | c.885C>G p.H295Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs112943477, COSV63252167; called by muse, mutect2, varscan2
- PNPLA2 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs772421048, COSV100352085; called by mutect2, varscan2
- PPP6C | c.700T>G p.C234G | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV65208824; called by muse, mutect2, varscan2
- PRPF3 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 27/88 reads (31%) | catalogued as COSV61394005; called by muse, mutect2, varscan2
- PTPN3 | c.2684G>T p.C895F | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV52709847; called by muse, mutect2, varscan2
- PTPN7 | c.227G>A p.R76H (on ENST00000495688; = p.R115H on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs752794133, COSV58311756; called by muse, mutect2, varscan2
- RP1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV55124082; called by muse, mutect2, varscan2
- SALL4 | c.2591G>A p.R864H | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53852661, COSV53855240; called by muse, mutect2, varscan2
- SIGLEC5 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 172/1214 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as rs770527359, COSV99707636; called by muse, varscan2
- SLC36A3 | c.1144+1G>T p.X382_splice | Splice Site (SNP) | VAF 38/93 reads (41%) | catalogued as COSV58857973; called by muse, mutect2, varscan2
- SLC7A3 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 163/292 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53229606; called by muse, mutect2, varscan2
- SRRM2 | c.6062G>A p.R2021Q | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.86); catalogued as rs376748808; called by muse, mutect2, varscan2
- THBS4 | c.2650T>C p.F884L | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.27); catalogued as COSV63470554; called by muse, mutect2, varscan2
- THSD7A | c.3095G>T p.C1032F | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101448784; called by muse, mutect2, varscan2
- TMEM121B | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.361); catalogued as rs1311138115, COSV100083254; called by muse, mutect2
- TMPRSS15 | c.23C>A p.S8Y | Missense Mutation (SNP) | VAF 94/254 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs774868000, COSV53039422; called by muse, mutect2, varscan2
- VRK2 | c.848G>A p.S283N | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV60879653; called by muse, mutect2
- WDFY3 | c.6577C>T p.R2193C | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as rs1481597056, COSV55711247; called by muse, mutect2, varscan2
- ZCCHC13 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV100272485, COSV100272539; called by muse, mutect2
- ZNF257 | c.913C>A p.Q305K | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.425); catalogued as COSV101448118, COSV71306944; called by muse, mutect2, varscan2
- ZNF334 | c.1996C>T p.R666C | Missense Mutation (SNP) | VAF 566/1423 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs763384880, COSV61617978; called by muse, mutect2, varscan2
- ZNF479 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as COSV100482836; called by muse, mutect2
- APC | c.1863_1866del p.Y622Gfs*7 | Frame Shift Del (DEL) | VAF 120/354 reads (34%) | called by pindel, varscan2
- CNTNAP5 | c.1294dup p.M432Nfs*7 | Frame Shift Ins (INS) | VAF 61/203 reads (30%) | called by mutect2, pindel, varscan2
- ZNF658 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 274/797 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHDC1 | c.4308C>T p.H1436= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs566131872, COSV99899471; called by muse, mutect2, varscan2
- ALDH16A1 | c.966G>A p.R322= | Silent (SNP) | VAF 63/218 reads (29%) | catalogued as COSV53195997; called by muse, mutect2, varscan2
- CEP85 | c.117G>T p.S39= | Silent (SNP) | VAF 80/185 reads (43%) | catalogued as COSV53329611; called by muse, mutect2, varscan2
- CREBBP | c.5064G>A p.T1688= | Silent (SNP) | VAF 55/112 reads (49%) | catalogued as rs972733992, COSV52136657; called by muse, mutect2, varscan2
- FAT3 | c.12351C>T p.F4117= | Silent (SNP) | VAF 48/89 reads (54%) | catalogued as COSV53159430; called by muse, mutect2, varscan2
- FLNA | c.1242C>T p.G414= | Silent (SNP) | VAF 43/79 reads (54%) | catalogued as rs782598234, COSV61049180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GUCY2F | c.3249C>A p.G1083= | Silent (SNP) | VAF 235/405 reads (58%) | catalogued as COSV54306983; called by muse, mutect2, varscan2
- LONRF3 | c.666G>A p.P222= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs749758658, COSV100504487; called by muse, mutect2, varscan2
- MAGEC3 | c.807C>A p.G269= | Silent (SNP) | VAF 243/405 reads (60%) | catalogued as COSV71610172; called by muse, mutect2, varscan2
- MTCL1 | c.4696C>A p.R1566= (on ENST00000306329 / NM_001378206.1; = p.R1247= on NM_015210.4) | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV60403389, COSV60410366; called by muse, mutect2
- MYLK | c.4293G>A p.P1431= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs370153686; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- OR2G6 | c.342C>T p.L114= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as COSV58574897; called by muse, mutect2, varscan2
- OR2T4 | c.234C>A p.I78= | Silent (SNP) | VAF 348/893 reads (39%) | catalogued as COSV63543293, COSV63544164, COSV63544348; called by muse, mutect2, varscan2
- OSGEP | c.369C>T p.A123= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as COSV52833530; called by muse, mutect2, varscan2
- PLEKHG2 | c.939A>G p.E313= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV99217684; called by muse, mutect2, varscan2
- PM20D1 | c.144C>T p.R48= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as COSV65649255; called by muse, mutect2, varscan2
- RAB11B | c.336C>T p.H112= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs143585074; called by muse, mutect2, varscan2
- RAD21 | c.510A>T p.I170= | Silent (SNP) | VAF 26/233 reads (11%) | catalogued as COSV52062628; called by muse, mutect2, varscan2
- ANK1 | c.5395-1195C>T | Intron (SNP) | VAF 28/84 reads (33%) | catalogued as rs1285784618, COSV55892152; called by muse, mutect2, varscan2
- WT1 | chr11:32439075 C>T | 5'Flank (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
